Gene-level copy-number profile of tumor specimen TCGA-61-2101-01A from TCGA case TCGA-61-2101, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 55.5 years (20,287 days).
Specimen TCGA-61-2101-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.604f0e46-eff5-4389-9197-27b7399b2ad9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2101-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f50ce541-f415-4935-9558-370513edb3e5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 3,123; copy number 2: 15,306; copy number 3: 21,801; copy number 4: 11,062; copy number 5: 7,141; copy number 6: 1,103; copy number 7: 32; copy number 8: 127; copy number 9: 82; copy number 12: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2101-01A-01D-0663-01): tumor purity 0.82, ploidy 3.23, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–738,106, 18 genes (within-gene range 0–3): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 262 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,723,830–48,906,937, 32 genes, copy number 7: RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2.
- chr4:72,280,969–76,802,426, 94 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr22:30,902,219–36,093,352, 136 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
